Surgical pathology report (de-identified scan), TCGA case TCGA-57-1992, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-57-1992-01A (Primary Tumor).

[page 1 of 4]
Not for Permanent Storage in Medical Records / Not Valid for Signing

Patient
MRN
Date of Service
Performing Facility
Ordering Provider
Result Provider
Report Name :Surgical Report

SEE REPORT

URGICAL PATHOLOGY REPORT

==== SPECIMEN DESCRIPTION: =====

- A. LEFT OVARIAN TUMOR & TUBE,
- B. SIGMOID COLON BIOPSY
- C. LEFT PELVIC SIDEWALL
- D. LEFT INFUNDIBULOPELVIC LIGAMENT
- E. SIGMOID COLON BIOPSY
- F. BLADDER BIOPSY
- G. RIGHT PELVIC SIDEWALL
- H. LEFT EXTERNAL ILIAC LYMPH NODES
- I. LEFT OBTURATOR LYMPH NODES
- J. LEFT PERIAORTIC LYMPH NODES
- K. OMENTUM
- L. DIAPHRAGMATIC CURETTINGS
- M. PERITONEAL BIOPSY
- N. UTERUS, CERVIX, RIGHT FALLOPIAN TUBE & OVARY

==== PRE-OPERATIVE DIAGNOSIS: =====

Ovarian tumor, incontinence

==== POST-OPERATIVE DIAGNOSIS: =====

Same

==== CLINICAL INFORMATION: =====

None provided

==== INTRAOPERATIVE CONSULTATION: =====

DIAGNOSIS: "Sample taken for genomic study,"

==== GROSS DESCRIPTION: =====

A. Received is a previously disrupted ovary, weighing 217 grams and measuring 17.2 x 10.2 x 4.8 cm. The attached fallopian tube measures 9.0 cm in length x 0.7 cm in diameter. There are scattered paratubal cysts, containing cloudy fluid and averaging 0.2 cm. Sectioning through the tube reveals a pinpoint lumen. The ovary has a tan-pink, congested, wrinkled outer surface. The cut surface of the ovary is multiloculated with raised friable tan-pink or orange excrescences, occupying 45% to 50% of the ovary. The remaining cut surface is pink-tan and wrinkled, with glistening areas and dull areas. The dull areas have a slightly granular appearance. The wall thickness ranges from 0.2 to 1.5 cm. Normal ovarian parenchyma is not identified. Representative sections are submitted in ten cassettes as follows: cassette 1 - fallopian tube; cassettes 2 through 10 - ovary.

[page 2 of 4]
Patient

MRN

Date of Service

Performing Facility

Ordering Provider

Result Provider

Report Name :Surgical Report

uterus was opened along the left lateral aspect. The serosa is pink-tan, congested, and smooth. The cervix measures 3.0 cm in length x 1.9 cm in width. The os is centrally located, patent, and measures 0.4 cm. The squamocolumnar junction is well defined. The remaining cervical canal is focally cystic with mucoid material. The endometrium measures 4.3 x 1.5 cm, with a 0.2 cm average thickness. The anterior endometrium displays pink-red, raised, polypoid-like lesion, measuring 1.0 x 0.6 x 0.3 cm. The lesion is confined to the mucosa. The myometrium is tan-pink, slightly trabeculated, and measures 1.5 cm in average thickness.

The right adnexa consist of a tan-pink congested fallopian tube, measuring 5.1 cm in length x 0.8 cm in diameter. There are several scattered paratubal cysts, containing cloudy fluid and measuring up to 1.5 cm in greatest dimension. Sectioning reveals a pinpoint lumen. The ovary is tan-pink, lobular, and measures 2.8 x 1.7 x 0.8 cm. Sectioning reveals a pink-white focally cystic cut surface. The cysts contain clear fluid and average 0.4 cm.

Representative sections are submitted in six cassettes as follows: cassette 1 - anterior cervix; cassette 2 - posterior cervix; cassette 3 - anterior endometrium with polyp; cassette 4 - posterior endometrium; cassettes 5 and 6 - right adnexa.

ADDENDUM

A. Additional sections of surface margin with lesion (orange inked surface) are submitted in cassettes 11 through 14.

==== MICROSCOPIC DESCRIPTION: =====

A-N. A total of thirty-five slides are examined. Sections from the grossly-described 17 cm left ovarian mass show high grade carcinoma with features of papillary serous carcinoma and transitional cell carcinoma. Focal clear cell appearance is also seen. The specimen is received with disruption. From the undisrupted area, the ovarian surface appears negative for carcinoma. Focal areas are suspicious for lymphovascular invasion (slides A4 and A6). Fallopian tubes are not involved by carcinoma. Other findings are listed in the diagnosis.

==== SPECIAL STAINS: =====

Immunostains for AE1/AE3 and calretinin on slide M show no tumor.

==== FINAL DIAGNOSIS: =====

LEFT OVARIAN TUMOR & FALLOPIAN TUBE, SALPINGO-OOPHORECTOMY:

1. HISTOLOGIC TYPE: CARCINOMA WITH FEATURES OF PAPILLARY SEROUS, TRANSITIONAL CELL, AND FOCAL CLEAR CELL

[page 3 of 4]
Patient

MRN

Date of Service

Performing Facility

Ordering Provider

Result Provider

Report Name

Surgical Report

The specimen consists of a red shaggy portion of soft tissue, measuring 0.9 x 0.8 x 0.2 cm. The specimen is serially sectioned, wrapped in lens paper, and submitted in one cassette.

C. The specimen consists of a 1.5 x 1.0 x 0.4 cm portion of tan-pink fibroadipose tissue. The outer surface is inked blue. The specimen is bisected and totally submitted in one cassette.

D. Received is a 1.5 x 1.0 x 0.6 cm portion of shaggy tan-pink soft tissue. The outer surface is inked blue. Sectioning reveals a pink-tan congested cut surface. The specimen is totally submitted in one cassette.

E. Received is a 1.4 x 0.9 x 0.4 cm portion of shaggy pink-tan fibroadipose tissue. The margin cannot be assessed. The specimen is trisected and submitted in one cassette.

F. Received are two tan-pink rubbery portions of congested soft tissue, measuring 2.7 x 1.0 x 0.3 cm and 2.6 x 1.4 x 0.3 cm. The larger fragment is inked blue. The specimen is totally submitted in two cassettes.

G. Received is a tan-pink membranous portion of soft tissue, measuring 1.4 x 0.8 x 0.2 cm. The specimen is serially sectioned, wrapped in lens paper, and totally submitted in one cassette.

H. Received is a 6.4 x 4.4 x 1.3 cm portion of lobular glistening yellow fibroadipose tissue. Sectioning reveals two possible lymph nodes, measuring 1.3 cm and 2.5 cm in greatest dimension. The larger lymph node displays fatty changes and is inked blue. The lymph nodes are totally submitted in two cassettes as follows: cassette 1 - smaller bisected lymph node and section of larger lymph node (inked blue); cassette 2 - remaining larger lymph node.

I. Received is a 5.8 x 2.8 x 1.4 cm aggregate of yellow fibroadipose tissue. Sectioning reveals five possible lymph nodes, ranging from 0.6 to 2.3 cm in greatest dimension. The largest lymph node appears to have fatty changes. The lymph nodes are totally submitted in two cassettes as follows: cassette 1 - four lymph nodes; cassette 2 - largest lymph node.

J. Received is a 4.3 x 3.3 x 1.1 cm aggregate of tan-yellow fibroadipose tissue. Sectioning reveals multiple tan-pink lymph nodes, ranging from 0.4 to 1.0 cm in greatest dimension. The specimen is totally submitted in two cassettes.

K. Received is an 18.3 x 10.3 x 1.0 cm portion of yellow lobulated adipose tissue, consistent with omentum. The surface is soft on palpation. Sectioning reveals a glistening yellow cut surface. No lesion is identified. Representative sections are submitted in one cassette.

L. Received is a 0.6 x 0.3 x 0.1 cm aggregate of pink-red soft tissue. The specimen is wrapped in lens paper and totally submitted in one cassette.

M. Received is a 0.9 x 0.8 x 0.3 cm shaggy portion of pink-tan soft tissue. The specimen is sectioned, wrapped in lens paper, and totally submitted in one cassette.

N. Received is a previously opened uterine corpus with cervix and attached right adnexa. The uterus weighs 82 grams and measures 6.9 x 4.3 x 3.7 cm. The

[page 4 of 4]
Not for Permanent Storage in Medical Records / Not Valid for Signing

Patient

MRN

Date of Service

Performing Facility

Ordering Provider

Result Provider

Report Name

:Surgical Report

2. HISTOLOGIC GRADE: G3 (POORLY DIFFERENTIATED)
3. EXTENT OF INVASION: pT1 (THE OVARIAN TUMOR MASS RECEIVED DISRUPTED, UNABLE TO EVALUATE RUPTURE, SEE MICROSCOPIC DESCRIPTION)
4. MARGINS: FROM UNDISRUPTED AREA, THE OVARIAN SURFACE IS FREE OF CARCINOMA
5. LYMPHOVASCULAR INVASION: FOCALLY SUSPICIOUS
6. REGIONAL LYMPH NODES: SEE SPECIMENS H THROUGH J
7. DISTANT METASTASIS: CANNOT BE ASSESSED
8. FALLOPIAN TUBE IS FREE OF CARCINOMA
- B. SIGMOID COLON, BIOPSY: NEGATIVE FOR CARCINOMA
- C. LEFT PELVIC SIDEWALL, BIOPSY: NEGATIVE FOR CARCINOMA
- D. LEFT INFUNDIBULOPELVIC LIGAMENT, BIOPSY: NEGATIVE FOR CARCINOMA
- E. SIGMOID COLON, BIOPSY: NEGATIVE FOR CARCINOMA
- F. BLADDER BIOPSY: NEGATIVE FOR CARCINOMA
- G. RIGHT PELVIC SIDEWALL, BIOPSY: NEGATIVE FOR CARCINOMA
- H. LEFT EXTERNAL ILIAC LYMPH NODES, BIOPSIES: TWO LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2)
- I. LEFT OBTURATOR LYMPH NODES, BIOPSIES: SIX LYMPH NODES, NEGATIVE FOR CARCINOMA (0/6)
- J. LEFT PERIAORTIC LYMPH NODES, BIOPSIES: NINE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/9)
- K. OMENTUM, BIOPSY: NEGATIVE FOR CARCINOMA
- L. DIAPHRAGMATIC CURETTINGS: FIBROADIPOSE TISSUE WITH MESOTHELIAL LINING, NEGATIVE FOR CARCINOMA
- M. PERITONEAL BIOPSY: FIBROVASCULAR TISSUE WITH MESOTHELIAL CELL HYPERPLASIA, NEGATIVE FOR CARCINOMA
- N. UTERUS, CERVIX, RIGHT FALLOPIAN TUBE & OVARY: NEGATIVE FOR CARCINOMA

A-MALIGNANT

DATE AND TIME OF R

Source: NCI Genomic Data Commons file 32270b94-b2ce-4837-902f-f9b98a7c19ab (TCGA-57-1992.77C742D8-BB0B-4EA9-9F61-9606C78C438E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).